MMRF case MMRF_2019 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a4b08d70-66f7-4236-abf1-17c2f4ad445d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.7 years (25,449 days); ISS stage: III; Days to last known disease status: 962 days (2.6 years); Days to last follow up: 962 days (2.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 148 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 123 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 150 days; Days to treatment end: 150 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 962.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 670 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 6.1 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 182 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Albumin 48 g/L; Total Protein 7.5 g/dL; Glucose 5.94 mmol/L; C-Reactive Protein 0.2 mg/dL.
- Day 85 (ECOG 1): Hemoglobin 6.51 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 365 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.33 mmol/L; Albumin 50 g/L; Total Protein 7.5 g/dL; Glucose 4.9 mmol/L.
- Day 182 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 8.27 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 4.8 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 268 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 8.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.05 mg/dL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 144 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.55 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 4.13 mmol/L.
- Day 449 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 7.36 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 145 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.5 mmol/L; Albumin 47 g/L; Total Protein 7.1 g/dL; Glucose 4.62 mmol/L.
- Day 539 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 6.98 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Albumin 49 g/L; Total Protein 7.5 g/dL; Glucose 4.29 mmol/L.
- Day 624 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 6.06 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 50 g/L; Total Protein 7.1 g/dL; Glucose 6.66 mmol/L.
- Day 771 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 6.97 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 5.12 mmol/L.
- Day 890 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 7.71 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.55 mmol/L; Albumin 49 g/L; Total Protein 7.1 g/dL; Glucose 5.61 mmol/L.
- Day 954 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 9.66 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.4 mmol/L; Albumin 48 g/L; Total Protein 7.4 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -11: Weight: 57 kg; Height: 154 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2019_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_2019_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
